Gene-level copy-number profile of tumor specimen TCGA-EJ-A65F-01A from TCGA case TCGA-EJ-A65F, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.4 years (21,681 days).
Specimen TCGA-EJ-A65F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.3b85eb5e-f92a-42fd-b8d0-be3823c2ce88.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-A65F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f88da76-7e03-49d4-b619-d0f23783bc7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 4,740; copy number 2: 47,606; copy number 3: 7,447.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-A65F-01A-21D-A30W-01): tumor purity 0.67, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:31,739,526–33,066,143, 22 genes (within-gene range 0–1): RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL.
- chr13:34,942,287–35,673,022, 1 gene (within-gene range 0–1): NBEA.
- chr13:35,251,070–35,699,938, 4 genes: PHBP13, MAB21L1, AL390071.1, LINC00445.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,354. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
